Somatic mutation profile of tumor specimen MP2PRT-PAVDUV-TMP1-A (aliquot MP2PRT-PAVDUV-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVDUV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (880 days).
Specimen MP2PRT-PAVDUV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31e5bd90-32d0-40e3-8f63-62e86d7606aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDUV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDUV-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe04db5b-465c-4d46-b805-4828b68b27e2

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf34 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 105/258 reads (41%) | catalogued as rs748338743, COSV100447456, COSV61372204; called by muse, mutect2, varscan2
- CXCR3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 285/775 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759360110; called by muse, mutect2, varscan2
- MGAT4C | c.51G>C p.M17I | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59838534; called by muse, mutect2, varscan2
- ROBO1 | c.3577C>A p.P1193T | Missense Mutation (SNP) | VAF 53/426 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV101459105, COSV71393301; called by muse, mutect2, varscan2
- INSR | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- JAM2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NIT2 | c.819del p.M273Ifs*18 | Frame Shift Del (DEL) | VAF 40/440 reads (9%) | called by mutect2, pindel
- PTPRQ | c.5663C>G p.A1888G (on ENST00000616559; = p.A1846G on NM_001145026.2) | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- RYR1 | c.11654G>A p.R3885Q | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPOCK3 | c.270C>G p.C90W | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- STAG2 | c.3649C>A p.P1217T | Missense Mutation (SNP) | VAF 215/457 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- UBL4A | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 158/704 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ZNF229 | c.1361T>A p.I454N | Missense Mutation (SNP) | VAF 50/566 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- CALCOCO1 | c.1176C>A p.G392= | Silent (SNP) | VAF 186/585 reads (32%) | called by muse, mutect2, varscan2
- CYP2C8 | c.504C>T p.F168= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as COSV64878701; called by muse, mutect2
- MANEAL | c.1194C>T p.I398= (on ENST00000373045 / NM_001113482.1; = p.I176= on NM_152496.2) | Silent (SNP) | VAF 152/502 reads (30%) | catalogued as rs879936658; called by muse, mutect2, varscan2
- AL353804.4 | n.31G>A | RNA (SNP) | VAF 14/408 reads (3%) | called by muse, mutect2
